Somatic mutation profile of tumor specimen HCM-CSHL-0907-C50-06A (aliquot HCM-CSHL-0907-C50-06A-21D-A882-36) from HCMI case HCM-CSHL-0907-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 74.6 years (27,246 days).
Specimen HCM-CSHL-0907-C50-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e273ec3-14ca-4ee4-852c-2b0611d46af3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0907-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0907-C50-10A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7653e603-ad2a-4f78-8ad1-156082a688a3

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 37/422 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ASXL2 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs770538687, COSV55452840, COSV99711309; called by muse, mutect2
- AUTS2 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 15/409 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1183738885, COSV61393013, COSV61399130; called by muse, mutect2
- CD300A | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs371212903; called by muse, mutect2
- EIF3B | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs551734577; called by muse, mutect2
- ERCC3 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.931); catalogued as rs1319949323; called by muse, mutect2
- FAM47B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 44/566 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs368902203, COSV61452510, COSV61454357; called by muse, mutect2
- HGH1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 72/862 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1200176463; called by muse, mutect2
- IGLV2-8 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.529); catalogued as rs1467923252; called by muse, mutect2
- MAPK15 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 20/593 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201591856; called by muse, mutect2
- MC3R | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 33/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371599272; called by muse, mutect2
- MUC16 | c.7190C>G p.S2397* | Nonsense Mutation (SNP) | VAF 15/367 reads (4%) | catalogued as COSV67476394; called by muse, mutect2
- NRSN2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 31/398 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs905109408, COSV66526790; called by muse, mutect2
- OCSTAMP | c.1120G>A p.V374I | Missense Mutation (SNP) | VAF 21/463 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV54096479; called by muse, mutect2
- PXDN | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765506698; called by muse, mutect2
- RNF126 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 24/506 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1457055494; called by muse, mutect2
- TTN | c.97822G>C p.D32608H (on ENST00000591111; = p.D25184H on NM_003319.4) | Missense Mutation (SNP) | VAF 15/413 reads (4%) | PolyPhen probably damaging (0.999); catalogued as COSV59966119; called by muse, mutect2
- AARS2 | c.1687A>G p.N563D | Missense Mutation (SNP) | VAF 26/536 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.412); called by muse, mutect2
- ARMC8 | c.1096G>A p.A366T (on ENST00000469044 / NM_001363941.2; = p.A352T on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CBARP | c.635C>A p.A212D (on ENST00000382477; = p.A192D on NM_152769.3) | Missense Mutation (SNP) | VAF 42/620 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.112); called by muse, mutect2
- CPD | c.180C>A p.H60Q | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.192); called by muse, mutect2
- CSTF3 | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 29/384 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2
- CYP11B1 | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 38/632 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- DNAH10 | c.3335T>C p.L1112P (on ENST00000409039; = p.L1051P on NM_207437.3) | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2
- DPEP1 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 27/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- FASTKD2 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- HIP1 | c.361T>G p.L121V | Missense Mutation (SNP) | VAF 18/499 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); called by muse, mutect2
- LAMB1 | c.1742C>G p.P581R | Missense Mutation (SNP) | VAF 18/519 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- MAP3K3 | c.1167_1169del p.S390del | In Frame Del (DEL) | VAF 33/296 reads (11%) | called by mutect2, pindel, varscan2
- PEPD | c.1260C>A p.H420Q | Missense Mutation (SNP) | VAF 25/776 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.081); called by muse, mutect2
- PRDM5 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNF141 | c.595A>G p.N199D | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2
- SLAMF1 | c.825A>T p.K275N | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.096); called by mutect2, varscan2
- SLC2A11 | c.707C>T p.S236F (on ENST00000345044 / NM_001024938.4; = p.S243F on NM_030807.5) | Missense Mutation (SNP) | VAF 30/584 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- TNMD | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 16/484 reads (3%) | called by muse, mutect2
- ZNF382 | c.1370T>A p.I457N | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZNF480 | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2
- ARHGAP10 | c.2091C>T p.S697= | Silent (SNP) | VAF 17/570 reads (3%) | called by muse, mutect2
- CTAG2 | c.387C>T p.S129= | Silent (SNP) | VAF 20/749 reads (3%) | called by muse, mutect2
- FAM155B | c.255C>A p.G85= | Silent (SNP) | VAF 17/561 reads (3%) | called by muse, mutect2
- FAM161B | c.723G>A p.T241= (on ENST00000651776; = p.T178= on NM_152445.3) | Silent (SNP) | VAF 38/486 reads (8%) | catalogued as rs754031440; called by muse, mutect2
- KBTBD7 | c.150G>T p.L50= | Silent (SNP) | VAF 30/516 reads (6%) | called by muse, mutect2
- KCNA5 | c.591G>A p.A197= | Silent (SNP) | VAF 41/610 reads (7%) | catalogued as rs1443012925; called by muse, mutect2
- KCNN3 | c.2079C>T p.A693= (on ENST00000618040 / NM_001204087.1; = p.A678= on NM_002249.6) | Silent (SNP) | VAF 48/418 reads (11%) | catalogued as rs747394806, COSV99679556; called by muse, varscan2
- MISP3 | c.921G>A p.E307= (on ENST00000269720; = p.E165= on NM_001291291.2) | Silent (SNP) | VAF 27/459 reads (6%) | called by muse, mutect2
- PHF8 | c.2592G>A p.L864= (on ENST00000357988 / NM_001184896.1; = p.L828= on NM_015107.3) | Silent (SNP) | VAF 14/479 reads (3%) | called by muse, mutect2
- TFE3 | c.99C>T p.D33= | Silent (SNP) | VAF 26/526 reads (5%) | called by muse, mutect2
- TMEM200B | c.432G>A p.T144= | Silent (SNP) | VAF 20/635 reads (3%) | called by muse, mutect2
- ZNF487 | c.222G>C p.L74= | Silent (SNP) | VAF 17/414 reads (4%) | called by muse, mutect2
- Z99774.2 | chr22:26670490 C>G | 5'Flank (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
